Surgical pathology report (de-identified scan), TCGA case TCGA-YD-A89C, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Spectrum Health, specimen TCGA-YD-A89C-06A (Metastatic).

[page 1 of 2]
ICD-O-3
Melanoma NOS 8720/3
Site: Liver C22.0
11/22/13

Research Gross Description

year-old female, liver mass, no history of chemo/radiation, primary upper extremity versus abdominal wall

Research Dx

Liver, left lateral hepatectomy:

Metastatic melanoma, two foci (9cm and 1 cm)

Research QC

Tumor:

75% tumor nuclei

25% necrosis

0% normal

Normal:

100% normal liver

Research Specimen

—

Specimen Process Time

Blood draw time:

Serum frozen time

Plasma frozen time

Buffy coat frozen time

Tissue:

Cold ischemia start time:

Formalin fixation start time:

Frozen start time:

Total cold ischemia time:

Formalin fixation stop time:

Total formalin fixation time:

Specimen Weight

Normal x 4 - 1. 332 mg 2. 236 mg 3. 434 mg 4. 256 mg

Tumor x 4 - 1. 195 mg 2. 471 mg 3. 468 mg 4. 158 mg

Specimen Size

Serum x 1

Plasma x 3

Buffy coat x 1

Cryovials x 8

Normal x 4

Tumor x 4

Metastatic x 0

FFPE x 8

Normal x 4

Tumor x 4

Metastatic x 0

[page 2 of 2]
Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file b709cdc8-b591-4d1f-989f-a08490e8dca8 (TCGA-YD-A89C.4AD900DD-AAC6-493D-A2C8-286FE3F43391.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).